Somatic mutation profile of tumor specimen HCM-BROD-0103-C71-01A (aliquot HCM-BROD-0103-C71-01A-11D-A78T-36) from HCMI case HCM-BROD-0103-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,295 days).
Specimen HCM-BROD-0103-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b063dd0-d6a8-4b11-bb26-62da38e4ce7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0103-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0103-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0845a68-aafc-4c7b-b405-657e28eca202

The open-access MAF lists 682 somatic variants for this specimen: 461 protein-altering or splice-affecting, 134 silent, 87 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 356, Silent 134, Intron 51, Frame Shift Del 48, Frame Shift Ins 19, Nonsense Mutation 18, 3'UTR 10, RNA 8, 5'Flank 7, In Frame Del 7, Splice Region 7, 5'UTR 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP5Z1 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 46/110 reads (42%) | catalogued as rs748724870; ClinVar: likely pathogenic; called by muse, mutect2
- CFAP44 | c.3175C>T p.R1059* | Nonsense Mutation (SNP) | VAF 185/390 reads (47%) | catalogued as rs1262272674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLDN16 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 227/524 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs765256758, CM015915, COSV53228629, COSV99290296; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COX14 | c.81dup p.Y28Vfs*39 | Frame Shift Ins (INS) | VAF 135/392 reads (34%) | catalogued as rs34028295; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ESCO2 | c.1131+1G>A p.X377_splice | Splice Site (SNP) | VAF 165/383 reads (43%) | catalogued as rs80359861, CS054187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 282/766 reads (37%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 61/374 reads (16%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 131/356 reads (37%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 56/152 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 90/263 reads (34%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 20/167 reads (12%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SETD2 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 102/242 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57431794, COSV57438402; called by muse, mutect2, varscan2
- SGCA | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 243/591 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); catalogued as rs371675217, CM163140, CM951149, COSV56249347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMLHE | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 114/215 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782785654, COSV57686403; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 303/600 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 300/640 reads (47%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 84/213 reads (39%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCC3 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1163700000, COSV53319611; called by muse, mutect2, varscan2
- ABCF1 | c.1369C>T p.R457C (on ENST00000326195 / NM_001025091.2; = p.R419C on NM_001090.3) | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772178279, COSV100400987; called by muse, mutect2, varscan2
- AC006059.2 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 90/177 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as rs1193298603, COSV58414753; called by muse, mutect2, varscan2
- ADAM8 | c.875+1G>A p.X292_splice | Splice Site (SNP) | VAF 35/46 reads (76%) | catalogued as COSV101291634; called by muse, mutect2, varscan2
- ADCY2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 97/189 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369487048, COSV57871248; called by muse, mutect2, varscan2
- AIFM3 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 186/388 reads (48%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.767); catalogued as rs150801089; called by muse, mutect2, varscan2
- ALAS1 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 262/546 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs773796345, COSV59630314; called by muse, mutect2, varscan2
- AMH | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1366538420; called by muse, mutect2
- ANKFY1 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs546745560; called by muse, mutect2
- ANKRD66 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as rs1046780145; called by muse, mutect2, varscan2
- ANKS1B | c.3131C>T p.P1044L (on ENST00000547776 / NM_152788.4; = p.P210L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/368 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs764918916, COSV100227903; called by muse, mutect2, varscan2
- AP1M2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 191/375 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs370653364; called by muse, mutect2, varscan2
- ARAP1 | c.1750G>A p.V584I (on ENST00000393609 / NM_001040118.2; = p.V339I on NM_015242.4) | Missense Mutation (SNP) | VAF 113/316 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201267929; called by muse, mutect2, varscan2
- ARHGEF10L | c.3695G>A p.R1232H | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748630782, COSV51431481; called by muse, mutect2
- ARHGEF17 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1046539421; called by muse, mutect2, varscan2
- ARRDC5 | c.724C>T p.R242W (on ENST00000381781; = p.R228W on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374682006; called by muse, mutect2
- ASAP2 | c.2357dup p.L787Afs*16 | Frame Shift Ins (INS) | VAF 86/194 reads (44%) | catalogued as rs773893016; called by mutect2, varscan2
- ASB2 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 99/105 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs765782110, COSV60112128; called by muse, mutect2, varscan2
- ASB8 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 62/429 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs747598837, COSV58350916; called by muse, mutect2, varscan2
- ATOX1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1026147447; called by muse, mutect2, varscan2
- ATP5IF1 | c.247_249del p.K83del | In Frame Del (DEL) | VAF 64/161 reads (40%) | catalogued as rs746429737; called by pindel, varscan2
- BAHCC1 | c.853_855del p.L285del | In Frame Del (DEL) | VAF 42/102 reads (41%) | catalogued as rs781915534; called by pindel, varscan2
- BCAR3 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 179/411 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs767751704; called by muse, mutect2, varscan2
- BCCIP | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs375172899; called by muse, mutect2, varscan2
- BCOR | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100652930; called by muse, mutect2
- BIVM-ERCC5 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 63/487 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs756778477; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3074C>T p.P1025L | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as rs759628522, COSV63245147; called by muse, mutect2
- BRD2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 238/558 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs771459465, COSV66374414; called by muse, mutect2, varscan2
- C14orf119 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 26/268 reads (10%) | catalogued as rs553918309, COSV52976492; called by muse, mutect2
- C2orf16 | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 224/473 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.062); catalogued as rs974882283; called by muse, mutect2, varscan2
- CACNA1H | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 168/364 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756266849, COSV61993629; called by muse, mutect2, varscan2
- CACNA1S | c.3760C>T p.R1254* | Nonsense Mutation (SNP) | VAF 283/647 reads (44%) | catalogued as rs200034567, COSV104423916; called by muse, mutect2, varscan2
- CARD9 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 224/464 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as rs369865691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAST | c.728C>T p.S243L (on ENST00000341926; = p.S326L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/375 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777835139; called by muse, mutect2, varscan2
- CBX2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs145409683; called by muse, mutect2, varscan2
- CDC42BPB | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 168/188 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1184748794, COSV100775556; called by muse, mutect2, varscan2
- CECR2 | c.3199G>A p.A1067T (on ENST00000342247 / NM_001290047.2; = p.A883T on NM_001290046.1) | Missense Mutation (SNP) | VAF 118/258 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs1193253270; called by muse, mutect2, varscan2
- CELSR1 | c.5032C>T p.R1678* | Nonsense Mutation (SNP) | VAF 160/271 reads (59%) | catalogued as rs1395192638, COSV53084327; called by muse, mutect2, varscan2
- CEP120 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 124/247 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs375645626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP250 | c.2206C>T p.R736* | Nonsense Mutation (SNP) | VAF 123/286 reads (43%) | catalogued as rs1345217165, COSV61170521; called by muse, mutect2, varscan2
- CHAD | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs1036430229; called by muse, mutect2
- CHD6 | c.3239C>T p.T1080M | Missense Mutation (SNP) | VAF 197/433 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs778940797; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 86/188 reads (46%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHRNA10 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 206/250 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV51703122; called by muse, mutect2, varscan2
- CHRNB1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 414/870 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs202080837, COSV53438818; called by muse, mutect2, varscan2
- CNBD2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs372174146; called by muse, mutect2, varscan2
- CNDP2 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs543311440, COSV60839699; called by muse, mutect2, varscan2
- CNKSR1 | c.1871G>A p.R624Q (on ENST00000374253 / NM_001297647.2; = p.R617Q on NM_006314.3) | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370754955; called by muse, mutect2, varscan2
- CNN1 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 111/232 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755937649, COSV52948059; called by muse, mutect2, varscan2
- CNNM3 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 109/217 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs375599243; called by muse, mutect2, varscan2
- CNOT2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 155/430 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs755578360, COSV57507432; called by muse, mutect2, varscan2
- COL26A1 | c.648dup p.G217Rfs*3 (on ENST00000313669 / NM_001278563.3; = p.G215Rfs*3 on NM_133457.4) | Frame Shift Ins (INS) | VAF 109/302 reads (36%) | catalogued as rs762324149; called by mutect2, varscan2
- CREBBP | c.5063C>T p.T1688M | Missense Mutation (SNP) | VAF 37/816 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781364836, COSV52127565; called by muse, mutect2
- CRYGA | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 239/498 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs759998672; called by muse, mutect2, varscan2
- CSGALNACT2 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 106/396 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs368373201; called by muse, mutect2, varscan2
- CSMD2 | c.7949C>T p.T2650M | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs766108599; called by muse, mutect2, varscan2
- CSMD3 | c.3638G>A p.R1213Q (on ENST00000297405 / NM_001363185.1; = p.R1109Q on NM_052900.3) | Missense Mutation (SNP) | VAF 18/542 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1437261459, COSV52248286; called by muse, mutect2
- CSNK1D | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 410/866 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs773629124; called by muse, mutect2, varscan2
- CTF1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753956418; called by muse, mutect2, varscan2
- CTPS2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 96/281 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs200862252, COSV100826912; called by muse, mutect2, varscan2
- CXorf66 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs937663859, COSV65169489; called by muse, mutect2, varscan2
- DDC | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 327/702 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1285477390, CM155193, COSV100779145; called by muse, mutect2, varscan2
- DDX54 | c.1975C>T p.R659W | Missense Mutation (SNP) | VAF 137/262 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs373380709; called by muse, mutect2, varscan2
- DEF8 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 112/218 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as rs770936185; called by muse, mutect2, varscan2
- DENND1C | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs757345339, COSV57568183; called by muse, mutect2, varscan2
- DENND4A | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921739451; called by muse, mutect2, varscan2
- DHX38 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs367927748; called by muse, mutect2, varscan2
- DIDO1 | c.4966C>T p.R1656W | Missense Mutation (SNP) | VAF 91/643 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs973386576, COSV99827276; called by muse, mutect2, varscan2
- DKKL1 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 190/608 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs553391194; called by muse, mutect2, varscan2
- DNAH1 | c.7186C>T p.R2396W | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs771741555; called by muse, mutect2, varscan2
- DNAI3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1389668154; called by muse, mutect2, varscan2
- DNAJB14 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs759384909; called by muse, mutect2, varscan2
- DNAJC6 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762184162; called by muse, mutect2, varscan2
- DNMT3A | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 167/362 reads (46%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1299885148; called by muse, mutect2, varscan2
- DNPH1 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs62417522; called by muse, mutect2, varscan2
- DNTTIP2 | c.2245C>T p.R749* | Nonsense Mutation (SNP) | VAF 84/212 reads (40%) | catalogued as rs757095161, COSV63283589, COSV63284176; called by muse, mutect2, varscan2
- DPP4 | c.2125+2T>C p.X709_splice | Splice Site (SNP) | VAF 103/223 reads (46%) | catalogued as rs1202315950; called by muse, mutect2, varscan2
- DYSF | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 234/582 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as rs146261069, COSV50459563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECEL1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 174/362 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs762886790, COSV58813980; called by muse, mutect2, varscan2
- ELMO2 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 115/232 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as COSV99281523; called by muse, mutect2, varscan2
- ELP3 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs867667800; called by muse, mutect2
- ENPP1 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 172/384 reads (45%) | catalogued as COSV62930392; called by muse, mutect2, varscan2
- EP400 | c.8330C>T p.T2777M | Missense Mutation (SNP) | VAF 156/323 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs1278138582; called by muse, mutect2, varscan2
- ERBB3 | c.1280del p.G427Afs*5 | Frame Shift Del (DEL) | VAF 120/726 reads (17%) | catalogued as COSV99031542, COSV99031637; called by mutect2, pindel, varscan2
- ERBB4 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 188/410 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.674); catalogued as rs775988789, COSV53516370, COSV99626233; called by muse, mutect2, varscan2
- ERFE | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 182/453 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.02); catalogued as COSV60137721; called by muse, mutect2, varscan2
- EZHIP | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 249/525 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs781803102, COSV57955344; called by muse, mutect2, varscan2
- F13A1 | c.2068G>A p.V690M | Missense Mutation (SNP) | VAF 234/511 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs762504395, COSV53559531; called by muse, mutect2, varscan2
- FAM151A | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 234/495 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs766394836; called by muse, mutect2, varscan2
- FAM222A | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 130/299 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.068); catalogued as rs1373319522; called by muse, mutect2, varscan2
- FARP1 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 162/305 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs747461832, COSV60348215; called by muse, mutect2, varscan2
- FARP2 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 313/657 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs151203664; called by muse, mutect2, varscan2
- FAT2 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 138/276 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs773729288, COSV55814904; called by muse, mutect2, varscan2
- FBXO36 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 161/335 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs747143681; called by muse, mutect2, varscan2
- FER1L4 | n.2878C>T | Splice Region (SNP) | VAF 105/229 reads (46%) | catalogued as rs894180329; called by muse, mutect2, varscan2
- FFAR4 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs762500408, COSV65159884; called by muse, mutect2
- FGFR4 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.063); catalogued as rs550870047; called by muse, mutect2, varscan2
- FHOD1 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 248/467 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775105803; called by muse, mutect2, varscan2
- FIBIN | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 104/233 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs367758269; called by muse, mutect2, varscan2
- FIZ1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 76/86 reads (88%) | SIFT tolerated (0.61); PolyPhen benign (0.04); catalogued as COSV99684385; called by muse, mutect2, varscan2
- FNDC5 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65105972; called by muse, mutect2
- FREM2 | c.2560G>A p.V854M | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs536960127, COSV54848795, COSV54853710; called by muse, mutect2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 40/85 reads (47%) | catalogued as rs781034813; called by mutect2, pindel, varscan2
- FUT1 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 324/715 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778160774, COSV59569709; called by muse, mutect2, varscan2
- GALNT10 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760742738, COSV99769956; called by muse, mutect2, varscan2
- GALNT16 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761614171, COSV61886308; called by muse, mutect2, varscan2
- GALNT17 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 204/393 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974898586, COSV61155556; called by muse, varscan2
- GALNT6 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 188/397 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1242187044; called by muse, mutect2, varscan2
- GLIS1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 126/296 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs779399927, COSV56556296; called by muse, mutect2, varscan2
- GLUD1 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.561); catalogued as rs142014578; called by muse, mutect2, varscan2
- GLYCTK | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 313/703 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs761292284; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 68/148 reads (46%) | catalogued as rs370114090; called by mutect2, varscan2
- GPD1L | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 36/658 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs775043567, COSV56989654; called by muse, mutect2
- GPR45 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV51523391; called by muse, mutect2, varscan2
- GRAMD4 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs761767100; called by muse, mutect2, varscan2
- GRB7 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 131/238 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs773643597, COSV100485412; called by muse, mutect2, varscan2
- GRIN3B | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1418162228; called by muse, mutect2
- HAND2 | c.247dup p.V83Gfs*260 | Frame Shift Ins (INS) | VAF 60/136 reads (44%) | catalogued as rs756064749; called by mutect2, varscan2
- HELZ2 | c.4909G>A p.D1637N (on ENST00000467148 / NM_001037335.2; = p.D1068N on NM_033405.3) | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1391635907; called by muse, mutect2, varscan2
- HFM1 | c.4163dup p.N1388Kfs*8 | Frame Shift Ins (INS) | VAF 20/42 reads (48%) | catalogued as rs759278255, COSV99646600; called by mutect2, varscan2
- HIPK2 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 180/379 reads (47%) | catalogued as COSV100702668; called by muse, mutect2, varscan2
- HK3 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 141/311 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs781200940, COSV52837709; called by muse, mutect2, varscan2
- HKDC1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 167/323 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs200818764, COSV63577650; called by muse, mutect2, varscan2
- HTT | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 134/146 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs955972991, COSV61858562; called by muse, mutect2, varscan2
- IGF1R | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 365/765 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375391097; called by muse, mutect2, varscan2
- IGSF10 | c.2803del p.M935Cfs*11 | Frame Shift Del (DEL) | VAF 175/466 reads (38%) | catalogued as COSV56783028; called by mutect2, pindel, varscan2
- IL1RAPL1 | c.1901C>A p.P634H | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV56291252; called by muse, mutect2, varscan2
- INAVA | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1370293917; called by muse, mutect2, varscan2
- INHBE | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs183609767, COSV99875280; called by muse, mutect2
- INTS1 | c.3496G>A p.V1166M | Missense Mutation (SNP) | VAF 195/426 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs984511351; called by muse, mutect2, varscan2
- IQSEC1 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 162/320 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs750405546; called by muse, mutect2, varscan2
- IQSEC2 | c.2833G>A p.D945N (on ENST00000642864 / NM_001111125.3; = p.D740N on NM_015075.2) | Missense Mutation (SNP) | VAF 140/290 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs781977015; called by muse, varscan2
- KANK4 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 253/511 reads (50%) | catalogued as rs1311359487, COSV62985750; called by muse, mutect2, varscan2
- KAZN | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 173/424 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1430957481; called by muse, mutect2, varscan2
- KCNA2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 63/451 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60369441; called by muse, mutect2, varscan2
- KCNN1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 60/454 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV55839606; called by muse, mutect2, varscan2
- KCNT1 | c.727C>T p.R243W (on ENST00000488444; = p.R262W on NM_020822.3) | Missense Mutation (SNP) | VAF 165/396 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs375711140; called by muse, mutect2, varscan2
- KIAA0513 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1300917628; called by muse, mutect2
- KIF14 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435446065, COSV100950704; called by muse, mutect2, varscan2
- KIF20B | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); catalogued as rs752762024, COSV53310077, COSV53314028; called by muse, mutect2, varscan2
- KIF4B | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 293/599 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200320925; called by muse, mutect2, varscan2
- KLHL17 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 196/475 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV58530694; called by muse, mutect2
- KREMEN1 | c.113C>T p.A38V (on ENST00000407188; = p.A40V on NM_032045.5) | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs749531697; called by muse, mutect2, varscan2
- KRT18 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 195/420 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs746898922, COSV101184077; called by muse, mutect2, varscan2
- KRT24 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs147201922; called by muse, mutect2, varscan2
- KRT86 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 429/918 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs376573652; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 172/328 reads (52%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LDB3 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 116/171 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1410128172, COSV53951568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDB3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 39/455 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs544084461, COSV53950265; called by muse, mutect2
- LINGO1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs973565369, COSV99051366; called by muse, mutect2, varscan2
- LINGO4 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 198/384 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759160503; called by muse, mutect2, varscan2
- LMBR1L | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs758249833, COSV57266924; called by muse, mutect2, varscan2
- LRCH1 | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs767339290, COSV100243603; called by muse, mutect2, varscan2
- MAP10 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 233/442 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV69364043; called by muse, mutect2, varscan2
- MAP3K20 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748593233, COSV64379442; called by muse, mutect2, varscan2
- MAP3K3 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs907003390, COSV62280597; called by muse, mutect2
- MAPRE3 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV51869188; called by muse, mutect2, varscan2
- MAST3 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 174/357 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as rs755807326, COSV53222737; called by muse, mutect2, varscan2
- MATN1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs377079004, COSV65651494; called by muse, mutect2, varscan2
- MBD5 | c.4033G>A p.V1345I | Missense Mutation (SNP) | VAF 179/898 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376249586; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MCM3AP | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 240/258 reads (93%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs762900381, COSV52436741; called by muse, mutect2, varscan2
- MDN1 | c.15157G>A p.A5053T | Missense Mutation (SNP) | VAF 175/329 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs114504442; called by muse, mutect2, varscan2
- MFAP1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 214/452 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1427724015, COSV51040268; called by muse, mutect2, varscan2
- MFSD5 | c.16T>A p.Y6N | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs762078925; called by muse, varscan2
- MICALL2 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748412801, COSV52515260; called by muse, mutect2, varscan2
- MIDEAS | c.2162+1G>A p.X721_splice | Splice Site (SNP) | VAF 174/195 reads (89%) | catalogued as COSV54098394; called by muse, mutect2, varscan2
- MRPL14 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 134/344 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1274184499; called by muse, mutect2, varscan2
- MTMR8 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs756598274, COSV66392809; called by muse, mutect2, varscan2
- MUC2 | c.2137G>A p.V713I | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs200274846; called by muse, mutect2, varscan2
- MUS81 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768086876, COSV57259687; called by muse, mutect2
- MYH2 | c.3584C>T p.A1195V | Missense Mutation (SNP) | VAF 462/942 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs373108053; ClinVar: uncertain significance; called by muse, varscan2
- MYH7B | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs371539151; called by muse, mutect2, varscan2
- MYO15A | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs1484818939; called by muse, mutect2
- MYO15A | c.5717C>T p.A1906V | Missense Mutation (SNP) | VAF 49/505 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs1053051442; called by muse, mutect2
- MYO19 | c.2794C>T p.R932W (on ENST00000614623 / NM_001163735.1; = p.R732W on NM_025109.5) | Missense Mutation (SNP) | VAF 130/297 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs765344804; called by muse, mutect2, varscan2
- MYT1 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 99/439 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60508209; called by muse, mutect2, varscan2
- NBPF10 | c.11053A>G p.K3685E | Missense Mutation (SNP) | VAF 49/520 reads (9%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.828); catalogued as rs782467629; called by muse, varscan2
- NCAN | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 189/395 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs777412280; called by muse, mutect2, varscan2
- NCL | c.594C>G p.D198E | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs572420764; called by muse, mutect2
- NF1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 192/426 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1350329837, COSV100645963, COSV62225453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSMF | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 325/690 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.557); catalogued as rs201458494; called by muse, mutect2, varscan2
- NUAK1 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 196/425 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs768508553; called by muse, mutect2, varscan2
- NUP62 | c.1339A>G p.M447V | Missense Mutation (SNP) | VAF 415/1457 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs748278801; called by muse, mutect2, varscan2
- OBSCN | c.9638C>T p.A3213V | Missense Mutation (SNP) | VAF 249/527 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.49); catalogued as rs375877740, COSV52758076; called by muse, mutect2, varscan2
- OCLN | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 384/798 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs539541122; called by muse, mutect2, varscan2
- PCARE | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 207/495 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs756152942; called by muse, mutect2, varscan2
- PCDHA10 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 631/1388 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as rs782398517, COSV100254313; called by muse, mutect2
- PCDHA6 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 330/724 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65344724; called by muse, mutect2, varscan2
- PCDHA7 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 354/772 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65343037; called by muse, mutect2, varscan2
- PCDHB12 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 59/1196 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1170138951, COSV53393512; called by muse, mutect2
- PCSK5 | c.3738dup p.C1247Mfs*13 | Frame Shift Ins (INS) | VAF 82/250 reads (33%) | catalogued as rs1446950988; called by mutect2, pindel, varscan2
- PDCD11 | c.1486_1488del p.K496del | In Frame Del (DEL) | VAF 136/242 reads (56%) | catalogued as rs763827025; called by pindel, varscan2
- PDE4D | c.1999G>A p.V667M (on ENST00000340635 / NM_001104631.2; = p.V531M on NM_006203.4) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs371593645; called by muse, mutect2, varscan2
- PDE4DIP | c.3244G>A p.V1082M | Missense Mutation (SNP) | VAF 146/414 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV57700738; called by muse, mutect2, varscan2
- PELP1 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs376346386; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 65/174 reads (37%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PGAP1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs572676406; called by muse, mutect2, varscan2
- PI4KA | c.4630G>A p.V1544M | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs201391035; called by muse, mutect2, varscan2
- PIEZO2 | c.5888G>A p.R1963Q | Missense Mutation (SNP) | VAF 150/303 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as rs1480686209; called by muse, mutect2, varscan2
- PIK3C2A | c.5045C>T p.A1682V | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs201133316, COSV56404414; called by muse, mutect2
- PLCG1 | c.3802G>A p.A1268T (on ENST00000373271 / NM_182811.2; = p.A1269T on NM_002660.3) | Missense Mutation (SNP) | VAF 139/250 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs761191435, COSV54820536; called by muse, mutect2, varscan2
- PLCL1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 177/390 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs140990771; called by muse, mutect2, varscan2
- PLEKHF1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV71410204; called by muse, mutect2
- PLXNC1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 140/343 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs748183392, COSV99313387; called by muse, mutect2, varscan2
- POU3F4 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 233/521 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs1250947545, COSV64539151; called by muse, mutect2, varscan2
- PPARGC1B | c.2929G>A p.G977R | Missense Mutation (SNP) | VAF 177/385 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754859721, COSV58528754; called by muse, mutect2, varscan2
- PPIL1 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 303/707 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs775079812; called by muse, mutect2, varscan2
- PPP6R2 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs377314097; called by muse, mutect2, varscan2
- PRPF6 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 328/1270 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs757991297, COSV53866068; called by muse, varscan2
- PRSS55 | c.141del p.S48Afs*36 | Frame Shift Del (DEL) | VAF 82/212 reads (39%) | catalogued as rs1404413098; called by mutect2, pindel, varscan2
- PSMC2 | c.423C>T p.G141= | Splice Region (SNP) | VAF 72/185 reads (39%) | catalogued as rs770391778; called by muse, mutect2, varscan2
- PTPRF | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs749276357; called by muse, mutect2
- PUF60 | c.914C>T p.P305L (on ENST00000526683 / NM_001362896.2; = p.P288L on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 151/374 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1309059867, COSV57592850; called by muse, mutect2, varscan2
- RAB22A | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174158375; called by muse, mutect2, varscan2
- RAB27A | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 243/555 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773233108, COSV61014510, COSV61017729; called by muse, mutect2, varscan2
- RAP1GAP | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs563762085; called by muse, mutect2
- RAPGEF6 | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 197/442 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs373182124; called by muse, mutect2, varscan2
- RBBP7 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 231/538 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV58112735; called by muse, mutect2, varscan2
- RBL2 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263233694; called by muse, mutect2, varscan2
- RBM11 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759324505; called by muse, mutect2, varscan2
- RBM19 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 240/516 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs767542752, COSV55701210; called by muse, mutect2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 70/138 reads (51%) | catalogued as rs751690893; called by mutect2, varscan2
- RBMX | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1442643187; called by muse, mutect2
- RCN1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs764118547, COSV50014326; called by muse, mutect2, varscan2
- RCOR3 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 195/429 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as rs1350236018, COSV65365749; called by muse, mutect2, varscan2
- RHBDD3 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 229/465 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1367170739; called by muse, mutect2, varscan2
- RHOXF1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54294358; called by muse, mutect2
- RIPK4 | c.1504G>A p.A502T (on ENST00000352483; = p.A454T on NM_020639.3) | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs763537495, COSV60186678; called by muse, mutect2, varscan2
- RIPOR3 | c.1346dup p.G450Rfs*44 | Frame Shift Ins (INS) | VAF 33/264 reads (13%) | catalogued as rs1283206212; called by mutect2, pindel, varscan2
- ROGDI | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 174/371 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs751703075; called by muse, mutect2, varscan2
- RPGRIP1L | c.3576A>C p.K1192N | Missense Mutation (SNP) | VAF 146/296 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50909228; called by muse, mutect2, varscan2
- RPL7 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV53582045, COSV53582105; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 78/174 reads (45%) | catalogued as rs756606313; called by mutect2, varscan2
- RYR1 | c.2923C>T p.R975W | Missense Mutation (SNP) | VAF 292/311 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs371278145; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAAL1 | c.474G>A p.R158= | Splice Region (SNP) | VAF 20/379 reads (5%) | catalogued as rs1331348531; called by muse, mutect2
- SALL3 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 250/504 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV73306074; called by muse, mutect2, varscan2
- SCN5A | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 109/233 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs199473084, CM097628; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SEC14L5 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750893044, COSV52037622; called by muse, mutect2, varscan2
- SEMA6C | c.2575G>C p.A859P | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.203); catalogued as rs762830558, COSV59004098; called by muse, varscan2
- SERHL2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 103/504 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as rs760043089; called by muse, mutect2, varscan2
- SETD1A | c.4792G>A p.V1598M | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52680586; called by muse, mutect2, varscan2
- SHFL | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 175/341 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as rs1456250797; called by muse, mutect2, varscan2
- SLC12A5 | c.2894G>A p.R965Q (on ENST00000454036 / NM_001134771.2; = p.R942Q on NM_020708.5) | Missense Mutation (SNP) | VAF 165/351 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.242); catalogued as rs760046175; called by muse, mutect2, varscan2
- SLC16A3 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 287/676 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs781598860, COSV66430214; called by muse, mutect2, varscan2
- SLC66A1 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs756272440, COSV100913177; called by muse, mutect2, varscan2
- SLIT3 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 154/368 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.219); catalogued as rs138617707; called by muse, mutect2, varscan2
- SMARCA4 | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 315/720 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1401056652; called by muse, mutect2, varscan2
- SMG1 | c.7037C>T p.T2346M | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs781293265, COSV67170758, COSV67173346; called by muse, mutect2, varscan2
- SMG7 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1348069150, COSV61631567; called by muse, mutect2, varscan2
- SMPD3 | c.1646-3dup | Splice Region (INS) | VAF 84/198 reads (42%) | catalogued as rs759774779; called by mutect2, varscan2
- SNRNP70 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 36/632 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55507463; called by muse, mutect2
- SNTG2 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 183/418 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs567924207, COSV57969357; called by muse, mutect2, varscan2
- SNX18 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.355); catalogued as COSV57992098; called by muse, mutect2, varscan2
- SPAAR | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 183/353 reads (52%) | PolyPhen benign (0.34); catalogued as rs899379535; called by muse, mutect2, varscan2
- SPDYE5 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 248/585 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1213080392; called by muse, mutect2, varscan2
- SPEG | c.8540G>A p.R2847Q | Missense Mutation (SNP) | VAF 129/324 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs560447047, COSV56669202; called by muse, mutect2, varscan2
- SPPL2C | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 143/294 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs759534395; called by muse, mutect2, varscan2
- SRSF3 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as rs760340535, COSV59672375; called by muse, mutect2
- SSC4D | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as rs1455559504; called by muse, mutect2, varscan2
- ST20 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs778309866; called by muse, mutect2, varscan2
- ST3GAL3 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 267/616 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99495621; called by muse, mutect2, varscan2
- STK36 | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 232/527 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs144654930; called by muse, mutect2, varscan2
- STK36 | c.3431G>A p.R1144H | Missense Mutation (SNP) | VAF 204/440 reads (46%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.899); catalogued as rs202055753; called by muse, mutect2, varscan2
- STK39 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 169/422 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs201684592, COSV63593979; called by muse, mutect2, varscan2
- STRADA | c.947G>A p.R316H (on ENST00000336174 / NM_001363786.1; = p.R279H on NM_153335.6) | Missense Mutation (SNP) | VAF 90/184 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs1305201887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STRN4 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 132/253 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1568390270, COSV54422331; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 199/395 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs748419749; called by muse, mutect2, varscan2
- TANC2 | c.4006C>T p.R1336C | Missense Mutation (SNP) | VAF 134/270 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1396830120; called by muse, mutect2, varscan2
- TBL1X | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 36/556 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs368633580; called by muse, mutect2
- TEDC1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 150/161 reads (93%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs372232345; called by muse, mutect2, varscan2
- TENM2 | c.5464C>T p.R1822C (on ENST00000518659 / NM_001122679.2; = p.R1583C on NM_001080428.3) | Missense Mutation (SNP) | VAF 166/388 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318739131, COSV69122789; called by muse, mutect2, varscan2
- TENM2 | c.8039G>A p.R2680H (on ENST00000518659 / NM_001122679.2; = p.R2441H on NM_001080428.3) | Missense Mutation (SNP) | VAF 69/378 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376795770; called by muse, mutect2, varscan2
- THEMIS | c.1218del p.V407Wfs*2 | Frame Shift Del (DEL) | VAF 29/173 reads (17%) | catalogued as rs1425728909; called by mutect2, pindel, varscan2
- TLE2 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 187/428 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs766498805; called by muse, mutect2, varscan2
- TLE3 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as rs756487725; called by muse, mutect2, varscan2
- TMEM104 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.303); catalogued as rs770423788; called by muse, mutect2, varscan2
- TMEM38A | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 146/377 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754662236, COSV51818067, COSV51819543; called by muse, mutect2, varscan2
- TMEM68 | c.965G>A p.R322H (on ENST00000434581 / NM_001363177.1; = p.R255H on NM_152417.3) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58169705; called by muse, mutect2, varscan2
- TMEM91 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 107/117 reads (91%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as rs370880269; called by muse, mutect2, varscan2
- TMEM92 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 126/329 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV100305205, COSV55946304; called by muse, mutect2, varscan2
- TMTC3 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 98/247 reads (40%) | catalogued as COSV57124709; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as rs1432818954, COSV59420053; called by muse, mutect2
- TNFRSF25 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs369890106; called by muse, mutect2, varscan2
- TNKS | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as rs1377624331; called by muse, mutect2
- TNPO2 | c.2350C>T p.R784C (on ENST00000425528 / NM_001382240.1; = p.R774C on NM_013433.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 173/399 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790430; called by muse, mutect2, varscan2
- TPBG | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.46); catalogued as rs1241381878; called by muse, mutect2
- TPD52L1 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 143/300 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs772348702, COSV59191130; called by muse, mutect2, varscan2
- TRAF7 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 189/399 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV58213894, COSV58215141, COSV58216343; called by muse, mutect2, varscan2
- TRIM66 | c.2938G>A p.G980R | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758937495; called by muse, mutect2, varscan2
- TRIR | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 227/479 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1306258758, COSV54406570; called by muse, mutect2, varscan2
- TRPC3 | c.271C>T p.R91W (on ENST00000379645 / NM_001366479.2; = p.R18W on NM_003305.2) | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53377890; called by muse, mutect2, varscan2
- TTC23 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 105/532 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs768266565; called by muse, mutect2, varscan2
- TTN | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as rs150954246, COSV60095193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TWNK | c.1592+5C>T | Splice Region (SNP) | VAF 101/346 reads (29%) | catalogued as rs1011909627; called by muse, mutect2, varscan2
- UGT1A6 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 266/598 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333719360, COSV59391983; called by muse, mutect2, varscan2
- UPK3A | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.794); catalogued as rs754224470; called by muse, mutect2, varscan2
- UQCR11 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 162/362 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs773886090; called by muse, mutect2, varscan2
- USH2A | c.12563A>G p.Y4188C | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV56383339; called by muse, mutect2
- VPS41 | c.1163del p.N388Ifs*15 | Frame Shift Del (DEL) | VAF 89/211 reads (42%) | catalogued as rs757692785; called by mutect2, pindel, varscan2
- VWA2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 201/308 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs142413003; called by muse, mutect2, varscan2
- WSCD2 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 304/691 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs950568945, COSV54585750; called by muse, mutect2, varscan2
- ZBTB20 | c.680C>T p.T227M (on ENST00000474710 / NM_001164342.2; = p.T154M on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/312 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV61845502; called by muse, mutect2, varscan2
- ZNF253 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 168/340 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs764373867, COSV63037856; called by muse, mutect2, varscan2
- ZNF318 | c.3580C>T p.R1194W | Missense Mutation (SNP) | VAF 208/407 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209398200; called by muse, mutect2, varscan2
- ZNF536 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as rs761513607; called by muse, mutect2, varscan2
- ZNF609 | c.4045C>T p.R1349W | Missense Mutation (SNP) | VAF 220/426 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1361713145; called by muse, mutect2, varscan2
- ZNF804A | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs765322307; called by muse, mutect2, varscan2
- ZNF837 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs771666763; called by muse, mutect2
- ABCC8 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM22 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 31/622 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); called by muse, mutect2
- ADGRG6 | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AMHR2 | c.1670A>G p.Q557R | Missense Mutation (SNP) | VAF 81/530 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD46 | c.5_7del p.S2del | In Frame Del (DEL) | VAF 70/178 reads (39%) | called by mutect2, pindel, varscan2
- ARHGAP45 | c.2082G>T p.E694D | Missense Mutation (SNP) | VAF 21/396 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ATRX | c.1074dup p.L359Tfs*3 | Frame Shift Ins (INS) | VAF 62/154 reads (40%) | called by mutect2, varscan2
- ATXN2 | c.1164G>T p.L388F (on ENST00000550104; = p.L228F on NM_002973.4) | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATXN7 | c.2340del p.T781Pfs*11 | Frame Shift Del (DEL) | VAF 179/412 reads (43%) | called by mutect2, pindel, varscan2
- BMP7 | c.885del p.S296Afs*72 | Frame Shift Del (DEL) | VAF 362/954 reads (38%) | called by mutect2, pindel, varscan2
- BRWD3 | c.1887G>T p.E629D | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2
- C19orf84 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- C4orf54 | c.1010del p.G337Efs*39 | Frame Shift Del (DEL) | VAF 80/203 reads (39%) | called by mutect2, pindel, varscan2
- CACNA1F | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 187/487 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CARD14 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- CBFA2T2 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 178/357 reads (50%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CBR1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 156/344 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCDC188 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CD5L | c.672dup p.K225Efs*7 | Frame Shift Ins (INS) | VAF 134/348 reads (39%) | called by mutect2, pindel, varscan2
- CDA | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 224/533 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- CDH11 | c.625del p.S209Rfs*27 | Frame Shift Del (DEL) | VAF 42/280 reads (15%) | called by mutect2, pindel, varscan2
- CDRT1 | c.1755G>A p.W585* | Nonsense Mutation (SNP) | VAF 14/456 reads (3%) | called by muse, mutect2
- CHD6 | c.3392A>G p.E1131G | Missense Mutation (SNP) | VAF 249/523 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLDN22 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 244/540 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COQ8B | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CPEB1 | c.123del p.F41Lfs*10 | Frame Shift Del (DEL) | VAF 82/219 reads (37%) | called by mutect2, pindel, varscan2
- CRACDL | c.2408G>T p.R803M | Missense Mutation (SNP) | VAF 91/505 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CSAD | c.487G>A p.A163T (on ENST00000444623 / NM_001244705.2; = p.A190T on NM_015989.5) | Missense Mutation (SNP) | VAF 256/619 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTDSPL | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CTTNBP2NL | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- CUZD1 | c.1508G>A p.C503Y | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2U1 | c.901del p.I301Sfs*18 | Frame Shift Del (DEL) | VAF 32/203 reads (16%) | called by mutect2, pindel, varscan2
- DCHS2 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 189/426 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- DIS3L2 | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 286/601 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DLG5 | c.2237G>T p.G746V | Missense Mutation (SNP) | VAF 133/290 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ESM1 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 141/322 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FEM1C | c.778dup p.R260Kfs*20 | Frame Shift Ins (INS) | VAF 96/236 reads (41%) | called by mutect2, varscan2
- FNIP1 | c.2980G>A p.A994T | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- FOXO1 | c.1730del p.G577Afs*5 | Frame Shift Del (DEL) | VAF 58/135 reads (43%) | called by mutect2, pindel, varscan2
- FOXO6 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT tolerated (0.78); called by muse, mutect2, varscan2
- FRMD7 | c.820T>C p.Y274H | Missense Mutation (SNP) | VAF 244/574 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRR2 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 81/371 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAREM2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- GBP7 | c.1293del p.H432Tfs*5 | Frame Shift Del (DEL) | VAF 96/616 reads (16%) | called by mutect2, pindel, varscan2
- GLRX2 | c.472del p.S158Vfs*22 (on ENST00000367439 / NM_197962.3; = p.S159Vfs*22 on NM_016066.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/84 reads (43%) | called by mutect2, varscan2
- HDAC1 | c.1277_1279del p.E426del | In Frame Del (DEL) | VAF 22/64 reads (34%) | called by pindel, varscan2
- HDAC2 | c.1375dup p.T459Nfs*4 | Frame Shift Ins (INS) | VAF 25/60 reads (42%) | called by mutect2, varscan2
- HERC1 | c.10912G>T p.G3638C | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPG2 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- HYLS1 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.107); called by muse, mutect2
- IFI16 | c.2297dup p.N766Kfs*9 (on ENST00000295809 / NM_001364867.2; = p.N710Kfs*9 on NM_005531.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 31/79 reads (39%) | called by mutect2, pindel, varscan2
- IL16 | c.2081C>A p.P694Q | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2
- INCENP | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- JPH3 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 165/424 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNK17 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- KDM6A | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM6B | c.3746T>C p.V1249A | Missense Mutation (SNP) | VAF 37/872 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- KDR | c.2152G>T p.G718W | Missense Mutation (SNP) | VAF 29/634 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); called by muse, mutect2
- KIF21A | c.2305dup p.T769Nfs*20 (on ENST00000361418 / NM_001378440.1; = p.T756Nfs*20 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 66/189 reads (35%) | called by mutect2, varscan2
- KNTC1 | c.1661del p.L554Yfs*3 | Frame Shift Del (DEL) | VAF 27/232 reads (12%) | called by mutect2, pindel, varscan2
- KRT14 | c.1103T>C p.M368T | Missense Mutation (SNP) | VAF 25/650 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.017); called by muse, mutect2
- LKAAEAR1 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 59/481 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LRCH2 | c.720G>T p.L240F | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRSAM1 | c.1698+2_1698+5del p.X566_splice | Splice Site (DEL) | VAF 238/549 reads (43%) | called by mutect2, pindel, varscan2
- LUZP4 | c.831G>C p.Q277H | Missense Mutation (SNP) | VAF 31/618 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.204); called by muse, mutect2
- MAZ | c.413del p.P138Rfs*28 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | called by mutect2, pindel, varscan2
- MBD3 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 44/734 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- MBTPS2 | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.17); called by muse, mutect2
- MFHAS1 | c.2188C>A p.L730I | Missense Mutation (SNP) | VAF 20/538 reads (4%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2
- MID1 | c.1856A>T p.D619V | Missense Mutation (SNP) | VAF 303/776 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MIGA1 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 96/207 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPEG1 | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2
- MSN | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 101/183 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH9 | c.2555A>G p.E852G | Missense Mutation (SNP) | VAF 30/758 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- MYT1 | c.1473C>A p.C491* | Nonsense Mutation (SNP) | VAF 216/378 reads (57%) | called by muse, varscan2
- NADK | c.22dup p.M8Nfs*5 | Frame Shift Ins (INS) | VAF 118/295 reads (40%) | called by mutect2, pindel, varscan2
- NAV3 | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.941); called by muse, mutect2
- NBEA | c.6747dup p.V2250Sfs*4 | Frame Shift Ins (INS) | VAF 78/207 reads (38%) | called by mutect2, varscan2
- NEMF | c.3154-3del | Splice Region (DEL) | VAF 53/63 reads (84%) | called by mutect2, varscan2
- NF1 | c.5812+6T>C | Splice Region (SNP) | VAF 68/160 reads (43%) | called by muse, mutect2, varscan2
- NFE2L2 | c.827_828del p.T276Sfs*7 | Frame Shift Del (DEL) | VAF 113/350 reads (32%) | called by pindel, varscan2
- NRXN2 | c.2035del p.A679Lfs*13 | Frame Shift Del (DEL) | VAF 101/239 reads (42%) | called by mutect2, pindel, varscan2
- NSD2 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 96/102 reads (94%) | called by muse, mutect2, varscan2
- OBSCN | c.9178T>G p.Y3060D | Missense Mutation (SNP) | VAF 206/453 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OBSCN | c.23074_23076del p.K7692del | In Frame Del (DEL) | VAF 121/242 reads (50%) | called by mutect2, pindel, varscan2
- OBSL1 | c.4271G>T p.G1424V | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.116); called by muse, mutect2
- OR10A4 | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by mutect2, varscan2
- PHF24 | c.703dup p.D235Gfs*3 | Frame Shift Ins (INS) | VAF 78/256 reads (30%) | called by mutect2, pindel, varscan2
- PHTF2 | c.1877G>A p.R626Q (on ENST00000248550 / NM_001366089.1; = p.R588Q on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- PLPPR3 | c.1547G>A p.R516H (on ENST00000520876 / NM_001270366.2; = p.R544H on NM_024888.2) | Missense Mutation (SNP) | VAF 85/255 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PML | c.138del p.A47Lfs*51 | Frame Shift Del (DEL) | VAF 225/574 reads (39%) | called by mutect2, pindel, varscan2
- PPFIA1 | c.1315dup p.M439Nfs*6 | Frame Shift Ins (INS) | VAF 86/195 reads (44%) | called by mutect2, pindel, varscan2
- PPP1R12C | c.1116del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 48/69 reads (70%) | called by mutect2, pindel, varscan2
- PTGFR | c.97del p.S33Qfs*2 | Frame Shift Del (DEL) | VAF 156/390 reads (40%) | called by mutect2, pindel, varscan2
- RAI1 | c.5179G>T p.G1727C | Missense Mutation (SNP) | VAF 41/648 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- RARG | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 56/518 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RARG | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- RNASEH2C | c.262_264del p.E88del | In Frame Del (DEL) | VAF 252/659 reads (38%) | called by mutect2, pindel, varscan2
- RNF19A | c.187del p.R63Efs*5 | Frame Shift Del (DEL) | VAF 132/369 reads (36%) | called by mutect2, pindel, varscan2
- SBF1 | c.5167C>T p.L1723F | Missense Mutation (SNP) | VAF 146/261 reads (56%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCPEP1 | c.273dup p.G92Wfs*4 | Frame Shift Ins (INS) | VAF 176/617 reads (29%) | called by mutect2, pindel, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 62/126 reads (49%) | called by mutect2, varscan2
- SETD1B | c.4765del p.Q1589Sfs*11 | Frame Shift Del (DEL) | VAF 40/105 reads (38%) | called by mutect2, pindel
- SGSM3 | c.1666del p.V556Sfs*21 | Frame Shift Del (DEL) | VAF 52/298 reads (17%) | called by mutect2, pindel, varscan2
- SH2D3A | c.134del p.G45Afs*4 | Frame Shift Del (DEL) | VAF 138/355 reads (39%) | called by mutect2, pindel, varscan2
- SIDT2 | c.1981+1del | Frame Shift Del (DEL) | VAF 29/221 reads (13%) | called by mutect2, pindel, varscan2
- SLC27A1 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 76/380 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SLC39A7 | c.638A>G p.Q213R | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); called by muse, varscan2
- SLC39A7 | c.696_717delinsGGAGAAATTTGTGAGAC p.V233Efs*73 | Frame Shift Del (DEL) | VAF 48/204 reads (24%) | called by pindel, varscan2*
- SLC45A4 | c.2398dup p.I800Nfs*13 (on ENST00000517878 / NM_001286646.2; = p.F747Ifs*10 on NM_001080431.2) | Frame Shift Ins (INS) | VAF 77/157 reads (49%) | called by mutect2, varscan2
- SSH1 | c.1519del p.L507Sfs*62 | Frame Shift Del (DEL) | VAF 125/323 reads (39%) | called by mutect2, pindel, varscan2
- ST3GAL1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 124/268 reads (46%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TAF1D | c.483del p.F161Lfs*7 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- TCF25 | c.192+1G>A p.X64_splice | Splice Site (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- THOP1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TOX4 | c.1337del p.P446Lfs*56 | Frame Shift Del (DEL) | VAF 31/113 reads (27%) | called by mutect2, pindel, varscan2
- TRAF3 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2
- TRAF3IP1 | c.768del p.E258Rfs*5 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | called by mutect2, pindel, varscan2
- TSGA10 | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 133/275 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.75262G>A p.A25088T (on ENST00000591111; = p.A17664T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/242 reads (5%) | PolyPhen benign (0.311); called by muse, mutect2
- TYK2 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- UBXN4 | c.839C>A p.A280D | Missense Mutation (SNP) | VAF 130/269 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UPF3B | c.1339C>T p.R447* (on ENST00000276201 / NM_080632.3; = p.R434* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 275/534 reads (51%) | called by muse, mutect2, varscan2
- USP30 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); called by muse, mutect2
- USP48 | c.2520_2521del p.C841Sfs*17 | Frame Shift Del (DEL) | VAF 38/166 reads (23%) | called by pindel, varscan2
- VWA1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 104/211 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- WT1 | c.508T>A p.S170T | Missense Mutation (SNP) | VAF 348/779 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- XPOT | c.1146del p.K382Nfs*2 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- YJU2 | c.875G>T p.R292M | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ZAP70 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 220/484 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ZDHHC21 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZFHX4 | c.6170del p.P2057Hfs*26 | Frame Shift Del (DEL) | VAF 46/128 reads (36%) | called by mutect2, varscan2
- ZNF226 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 152/316 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF578 | c.1048A>G p.K350E | Missense Mutation (SNP) | VAF 215/248 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF726 | c.1637_1638del p.F546* | Frame Shift Del (DEL) | VAF 132/402 reads (33%) | called by mutect2, pindel, varscan2
- ZSCAN2 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 13/428 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- ABHD17A | c.90G>A p.P30= | Silent (SNP) | VAF 227/490 reads (46%) | catalogued as rs1436301012, COSV99171193; called by mutect2, varscan2
- ALPG | c.1269C>T p.G423= | Silent (SNP) | VAF 92/227 reads (41%) | called by muse, mutect2, varscan2
- ALPP | c.1278C>T p.G426= | Silent (SNP) | VAF 112/885 reads (13%) | catalogued as COSV67397178, COSV67398338; called by muse, mutect2, varscan2
- ANKRD11 | c.7749C>T p.N2583= | Silent (SNP) | VAF 332/715 reads (46%) | catalogued as rs138161949; called by muse, mutect2, varscan2
- APBA1 | c.504C>T p.Y168= | Silent (SNP) | VAF 282/593 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.996C>T p.Y332= | Silent (SNP) | VAF 196/414 reads (47%) | catalogued as rs782314375, COSV53639264; called by muse, mutect2, varscan2
- ATP10A | c.2607C>T p.D869= | Silent (SNP) | VAF 62/124 reads (50%) | catalogued as rs372023252; called by muse, mutect2, varscan2
- BACH2 | c.624C>T p.P208= | Silent (SNP) | VAF 26/397 reads (7%) | catalogued as rs991761443, COSV57608526; called by muse, mutect2
- BCL11B | c.2241C>T p.N747= (on ENST00000357195 / NM_001282237.2; = p.N676= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 297/321 reads (93%) | called by muse, mutect2, varscan2
- BEND3 | c.2349C>T p.Y783= | Silent (SNP) | VAF 49/561 reads (9%) | catalogued as rs541825404; called by muse, mutect2
- BEST4 | c.42C>T p.F14= | Silent (SNP) | VAF 191/446 reads (43%) | catalogued as rs754871004, COSV64734573; called by muse, mutect2, varscan2
- BOP1 | c.1614G>A p.T538= | Silent (SNP) | VAF 45/847 reads (5%) | catalogued as rs1221188898; called by muse, mutect2
- BZW1 | c.1119C>T p.S373= | Silent (SNP) | VAF 83/190 reads (44%) | catalogued as rs527916518; called by muse, mutect2, varscan2
- CABIN1 | c.4995C>T p.S1665= | Silent (SNP) | VAF 41/463 reads (9%) | catalogued as rs201868169; called by muse, mutect2
- CBX6 | c.930G>A p.P310= | Silent (SNP) | VAF 203/434 reads (47%) | catalogued as rs771912988; called by muse, mutect2, varscan2
- CBX7 | c.726C>A p.G242= | Silent (SNP) | VAF 76/172 reads (44%) | catalogued as rs1319175001; called by muse, mutect2, varscan2
- CCDC3 | c.693G>A p.A231= | Silent (SNP) | VAF 274/555 reads (49%) | catalogued as rs763966247, COSV66558407, COSV66560237; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1491T>C p.N497= | Silent (SNP) | VAF 36/211 reads (17%) | called by muse, mutect2, varscan2
- CFLAR | c.1278C>T p.C426= | Silent (SNP) | VAF 79/174 reads (45%) | called by muse, mutect2, varscan2
- CHD5 | c.3813C>T p.D1271= | Silent (SNP) | VAF 127/319 reads (40%) | catalogued as rs201484104, COSV52422737; called by muse, mutect2, varscan2
- CHST8 | c.639C>T p.A213= | Silent (SNP) | VAF 165/174 reads (95%) | catalogued as rs987438640, COSV52860085; called by muse, mutect2, varscan2
- CLVS1 | c.921C>T p.H307= | Silent (SNP) | VAF 97/204 reads (48%) | catalogued as rs372058481; called by muse, mutect2, varscan2
- CNNM4 | c.1269C>T p.Y423= | Silent (SNP) | VAF 305/624 reads (49%) | catalogued as rs758866379, COSV65661123; called by muse, mutect2, varscan2
- CNTRL | c.1674C>T p.S558= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as rs1435556167; called by muse, mutect2, varscan2
- CRB1 | c.1074C>A p.S358= | Silent (SNP) | VAF 256/559 reads (46%) | called by muse, mutect2, varscan2
- DAG1 | c.2205A>G p.E735= | Silent (SNP) | VAF 345/753 reads (46%) | called by muse, mutect2, varscan2
- DCC | c.2757G>A p.S919= | Silent (SNP) | VAF 112/592 reads (19%) | catalogued as rs144874430; called by muse, mutect2, varscan2
- DENND2B | c.534G>A p.S178= | Silent (SNP) | VAF 24/324 reads (7%) | catalogued as COSV58201446; called by muse, mutect2
- DHX30 | c.3051C>T p.G1017= (on ENST00000445061 / NM_138615.3; = p.G978= on NM_014966.3) | Silent (SNP) | VAF 31/206 reads (15%) | catalogued as rs767490754; called by muse, mutect2, varscan2
- DHX57 | c.120C>T p.G40= | Silent (SNP) | VAF 126/341 reads (37%) | catalogued as rs772879942, COSV99770183; called by mutect2, varscan2
- DIDO1 | c.6C>T p.D2= | Silent (SNP) | VAF 77/126 reads (61%) | catalogued as rs59453100; called by muse, mutect2, varscan2
- DNAJB8 | c.270C>T p.G90= | Silent (SNP) | VAF 216/449 reads (48%) | called by muse, mutect2, varscan2
- DVL1 | c.1668G>A p.P556= (on ENST00000378888 / NM_001330311.2; = p.P531= on NM_004421.3) | Silent (SNP) | VAF 107/245 reads (44%) | catalogued as rs746715259; called by muse, mutect2, varscan2
- DVL1 | c.273G>A p.A91= | Silent (SNP) | VAF 149/364 reads (41%) | catalogued as rs201640020; called by muse, mutect2, varscan2
- EFCAB5 | c.1446T>C p.S482= | Silent (SNP) | VAF 107/234 reads (46%) | called by muse, mutect2, varscan2
- ENTPD7 | c.186C>T p.Y62= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs374024141; called by muse, mutect2, varscan2
- FAT1 | c.2574G>A p.T858= | Silent (SNP) | VAF 135/286 reads (47%) | catalogued as rs376884651; called by muse, mutect2, varscan2
- FCGRT | c.840G>A p.A280= | Silent (SNP) | VAF 193/573 reads (34%) | catalogued as rs768621432, COSV99571236; called by muse, mutect2, varscan2
- FNDC8 | c.540C>T p.D180= | Silent (SNP) | VAF 52/94 reads (55%) | called by mutect2, varscan2
- FZD1 | c.1731C>T p.Y577= | Silent (SNP) | VAF 141/297 reads (47%) | called by muse, mutect2, varscan2
- GABBR1 | c.252C>T p.N84= | Silent (SNP) | VAF 181/352 reads (51%) | catalogued as rs568472804, COSV63542674; called by muse, mutect2, varscan2
- GMEB2 | c.72C>T p.D24= | Silent (SNP) | VAF 111/398 reads (28%) | catalogued as rs775670456, COSV56606206; called by muse, mutect2, varscan2
- GOLGA8R | c.1461C>T p.C487= | Silent (SNP) | VAF 16/66 reads (24%) | called by mutect2, varscan2
- GRK7 | c.51G>A p.L17= | Silent (SNP) | VAF 103/215 reads (48%) | called by muse, mutect2
- GSPT2 | c.1356C>T p.S452= | Silent (SNP) | VAF 208/437 reads (48%) | catalogued as rs1557348951, COSV61214276; called by muse, mutect2, varscan2
- HGFAC | c.786C>T p.T262= | Silent (SNP) | VAF 162/174 reads (93%) | catalogued as rs746573048; called by muse, mutect2, varscan2
- ICOS | c.570A>G p.K190= | Silent (SNP) | VAF 147/333 reads (44%) | called by muse, mutect2, varscan2
- IGSF9 | c.3519C>T p.P1173= (on ENST00000368094 / NM_001135050.2; = p.P1157= on NM_020789.4) | Silent (SNP) | VAF 234/512 reads (46%) | catalogued as rs748504173, COSV100231010; called by muse, mutect2, varscan2
- ILDR2 | c.1803C>T p.R601= | Silent (SNP) | VAF 149/281 reads (53%) | catalogued as rs765636434; called by muse, mutect2, varscan2
- IRGQ | c.1515C>T p.D505= | Silent (SNP) | VAF 126/279 reads (45%) | catalogued as rs756048262; called by muse, mutect2, varscan2
- IRS2 | c.1854G>A p.A618= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- ITGA5 | c.1806G>A p.S602= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs772385573, COSV53216451; called by muse, mutect2, varscan2
- ITLN1 | c.513G>A p.T171= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs142129957, COSV58275918; called by muse, mutect2, varscan2
- JARID2 | c.1188G>A p.A396= | Silent (SNP) | VAF 120/249 reads (48%) | catalogued as rs149943687; called by muse, mutect2, varscan2
- KEAP1 | c.570C>T p.F190= | Silent (SNP) | VAF 222/465 reads (48%) | catalogued as COSV50640203; called by muse, mutect2, varscan2
- KIF4B | c.1407G>A p.L469= | Silent (SNP) | VAF 34/490 reads (7%) | called by muse, mutect2
- LMTK2 | c.3633C>T p.S1211= | Silent (SNP) | VAF 184/424 reads (43%) | catalogued as rs764356535; called by muse, mutect2, varscan2
- MAP4K1 | c.642G>A p.P214= | Silent (SNP) | VAF 137/149 reads (92%) | catalogued as rs35922303; called by muse, mutect2, varscan2
- MCOLN1 | c.99G>A p.P33= | Silent (SNP) | VAF 276/555 reads (50%) | catalogued as rs760801246; called by muse, mutect2, varscan2
- MCUB | c.702A>G p.A234= | Silent (SNP) | VAF 50/315 reads (16%) | called by muse, mutect2, varscan2
- MED8 | c.636G>A p.T212= | Silent (SNP) | VAF 44/818 reads (5%) | catalogued as rs776989822, COSV51939845; called by muse, mutect2
- MEIS1 | c.81G>A p.P27= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as COSV55486034; called by muse, mutect2
- METTL22 | c.666C>T p.I222= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as rs530526653, COSV50837663; called by muse, mutect2
- MICAL3 | c.2745C>T p.A915= | Silent (SNP) | VAF 245/528 reads (46%) | catalogued as rs761909172; called by muse, mutect2, varscan2
- MOGAT3 | c.888C>T p.P296= | Silent (SNP) | VAF 84/180 reads (47%) | catalogued as rs781425954, COSV56174058; called by muse, mutect2, varscan2
- MSH4 | c.168G>A p.T56= | Silent (SNP) | VAF 290/579 reads (50%) | catalogued as rs774095092, COSV54204248; called by muse, mutect2, varscan2
- MTPAP | c.561C>T p.D187= | Silent (SNP) | VAF 234/566 reads (41%) | catalogued as rs747737059; called by muse, mutect2, varscan2
- MUC2 | c.3738C>T p.N1246= | Silent (SNP) | VAF 219/280 reads (78%) | catalogued as rs376760340; called by muse, varscan2
- MUC3A | c.8919G>A p.P2973= | Silent (SNP) | VAF 101/397 reads (25%) | catalogued as rs770825182, COSV60210171; called by muse, mutect2, varscan2
- MYO15A | c.2016C>T p.S672= | Silent (SNP) | VAF 52/109 reads (48%) | called by muse, mutect2, varscan2
- MYO16 | c.2721C>T p.Y907= | Silent (SNP) | VAF 112/228 reads (49%) | catalogued as rs751174402, COSV51788268; called by muse, mutect2, varscan2
- MYO1C | c.2046G>A p.T682= (on ENST00000648651 / NM_001080779.2; = p.T647= on NM_033375.5) | Silent (SNP) | VAF 346/742 reads (47%) | catalogued as rs757819967, COSV100704286; called by muse, mutect2, varscan2
- MYOD1 | c.519C>T p.G173= | Silent (SNP) | VAF 218/434 reads (50%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2214G>A p.L738= | Silent (SNP) | VAF 14/330 reads (4%) | called by muse, mutect2
- NCEH1 | c.393G>A p.P131= (on ENST00000538775; = p.P99= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 252/614 reads (41%) | catalogued as rs149025248; called by muse, mutect2, varscan2
- NHLRC1 | c.729C>T p.D243= | Silent (SNP) | VAF 293/616 reads (48%) | catalogued as rs146420615; called by muse, mutect2, varscan2
- NRN1 | c.138C>T p.G46= | Silent (SNP) | VAF 134/318 reads (42%) | catalogued as COSV55205507; called by muse, mutect2, varscan2
- NUMA1 | c.1110G>A p.L370= | Silent (SNP) | VAF 20/568 reads (4%) | catalogued as rs1253962410; called by muse, mutect2
- NUP107 | c.2049G>A p.A683= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as rs149594646; called by muse, mutect2, varscan2
- NUTM2E | c.1680G>A p.P560= | Silent (SNP) | VAF 25/299 reads (8%) | catalogued as rs773013947; called by muse, mutect2, varscan2
- OR12D2 | c.207C>A p.I69= | Silent (SNP) | VAF 13/314 reads (4%) | catalogued as COSV65826244; called by muse, mutect2
- PABPC3 | c.36G>A p.S12= | Silent (SNP) | VAF 122/232 reads (53%) | catalogued as COSV55799719; called by muse, mutect2, varscan2
- PCDHA3 | c.708C>T p.N236= | Silent (SNP) | VAF 186/387 reads (48%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.711G>A p.A237= | Silent (SNP) | VAF 205/434 reads (47%) | catalogued as COSV53935044; called by muse, mutect2, varscan2
- PDILT | c.1632C>T p.Y544= | Silent (SNP) | VAF 273/579 reads (47%) | catalogued as rs374255958, COSV56701088; called by muse, mutect2, varscan2
- PDPR | c.765G>A p.P255= | Silent (SNP) | VAF 225/1114 reads (20%) | catalogued as rs1427698397; called by muse, varscan2
- PDZK1IP1 | c.30C>T p.G10= | Silent (SNP) | VAF 87/201 reads (43%) | catalogued as rs377640107; called by muse, mutect2, varscan2
- PEAK3 | c.255G>A p.P85= | Silent (SNP) | VAF 83/178 reads (47%) | catalogued as rs1000951796; called by muse, mutect2, varscan2
- PLEKHM1 | c.339G>A p.T113= | Silent (SNP) | VAF 321/705 reads (46%) | catalogued as rs764582224; called by muse, mutect2, varscan2
- PLP1 | c.342C>T p.S114= | Silent (SNP) | VAF 221/492 reads (45%) | catalogued as rs756334357; called by muse, mutect2, varscan2
- PLXND1 | c.3153C>T p.F1051= | Silent (SNP) | VAF 214/477 reads (45%) | catalogued as rs151241774; called by muse, mutect2, varscan2
- PRDM2 | c.4951C>A p.R1651= | Silent (SNP) | VAF 75/153 reads (49%) | called by muse, mutect2, varscan2
- PRPF6 | c.2802C>T p.A934= | Silent (SNP) | VAF 206/595 reads (35%) | catalogued as rs755778991, COSV53874009; called by muse, mutect2, varscan2
- PTPRU | c.2031C>A p.A677= | Silent (SNP) | VAF 272/658 reads (41%) | catalogued as rs1364723313; called by muse, mutect2, varscan2
- PXN | c.1137C>T p.P379= (on ENST00000228307 / NM_001080855.3; = p.P345= on NM_002859.4) | Silent (SNP) | VAF 150/339 reads (44%) | catalogued as rs754778377; called by muse, mutect2, varscan2
- RBM5 | c.216C>T p.S72= | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as rs765156684; called by muse, mutect2, varscan2
- RNFT2 | c.243G>A p.S81= | Silent (SNP) | VAF 23/336 reads (7%) | catalogued as rs774198334; called by muse, mutect2
- SAFB2 | c.2481C>T p.S827= | Silent (SNP) | VAF 118/276 reads (43%) | catalogued as rs769071549; called by muse, mutect2, varscan2
- SHLD3 | c.102G>A p.P34= | Silent (SNP) | VAF 80/188 reads (43%) | catalogued as rs1285157985; called by muse, mutect2, varscan2
- SIN3A | c.3309G>A p.E1103= | Silent (SNP) | VAF 75/221 reads (34%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1059C>T p.D353= | Silent (SNP) | VAF 110/222 reads (50%) | catalogued as rs757351459, COSV53763683; called by muse, mutect2, varscan2
- SLC16A6 | c.417C>T p.I139= | Silent (SNP) | VAF 119/262 reads (45%) | called by muse, mutect2, varscan2
- SLC17A2 | c.1119C>T p.Y373= | Silent (SNP) | VAF 93/203 reads (46%) | catalogued as rs773778901, COSV99614618; called by muse, mutect2, varscan2
- SLC22A23 | c.1365C>T p.H455= | Silent (SNP) | VAF 194/450 reads (43%) | catalogued as rs138000137; called by muse, mutect2, varscan2
- SLC26A4 | c.183C>A p.A61= | Silent (SNP) | VAF 35/599 reads (6%) | called by muse, mutect2
- SLC7A6 | c.1146C>T p.I382= | Silent (SNP) | VAF 147/264 reads (56%) | catalogued as rs767868194; called by muse, mutect2, varscan2
- SLITRK5 | c.2160C>T p.G720= | Silent (SNP) | VAF 101/199 reads (51%) | catalogued as COSV61521388; called by muse, mutect2, varscan2
- SPATA2L | c.765G>A p.A255= | Silent (SNP) | VAF 47/313 reads (15%) | catalogued as rs778118142, COSV99232610; called by muse, mutect2, varscan2
- SPDL1 | c.1236A>G p.A412= | Silent (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- SRL | c.705G>A p.E235= | Silent (SNP) | VAF 140/327 reads (43%) | called by muse, mutect2, varscan2
- SRMS | c.879G>A p.S293= | Silent (SNP) | VAF 110/440 reads (25%) | catalogued as rs756318161, COSV99420529; called by muse, mutect2, varscan2
- SRPK3 | c.1038G>A p.A346= | Silent (SNP) | VAF 178/394 reads (45%) | catalogued as rs376127813; called by muse, mutect2, varscan2
- STAP2 | c.861G>A p.P287= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as rs145032917, COSV99696649; called by muse, mutect2, varscan2
- STRC | c.396C>T p.H132= | Silent (SNP) | VAF 64/244 reads (26%) | called by mutect2, varscan2
- SUN1 | c.1059G>A p.S353= (on ENST00000405266 / NM_001367651.1; = p.S233= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 77/176 reads (44%) | catalogued as rs776253918; called by muse, mutect2, varscan2
- SYAP1 | c.750C>T p.P250= | Silent (SNP) | VAF 127/334 reads (38%) | catalogued as COSV101204909; called by muse, mutect2, varscan2
- TAPBPL | c.1152C>T p.V384= | Silent (SNP) | VAF 26/500 reads (5%) | called by muse, mutect2
- TBC1D31 | c.915C>T p.L305= | Silent (SNP) | VAF 182/431 reads (42%) | called by muse, mutect2, varscan2
- THRA | c.468G>A p.Q156= | Silent (SNP) | VAF 21/598 reads (4%) | called by muse, mutect2
- TIMM17A | c.90C>T p.I30= | Silent (SNP) | VAF 36/288 reads (13%) | catalogued as rs1478807310; called by muse, mutect2, varscan2
- TMCO6 | c.837T>C p.H279= | Silent (SNP) | VAF 143/329 reads (43%) | catalogued as rs377210720; called by muse, mutect2, varscan2
- TMEM51 | c.402C>T p.Y134= | Silent (SNP) | VAF 68/125 reads (54%) | catalogued as rs748204095; called by muse, mutect2, varscan2
- TRABD2A | c.444C>T p.Y148= | Silent (SNP) | VAF 236/523 reads (45%) | catalogued as rs371560834; called by muse, mutect2, varscan2
- TRERF1 | c.129C>T p.G43= | Silent (SNP) | VAF 256/579 reads (44%) | catalogued as rs138805200; called by muse, varscan2
- TTN | c.82155G>A p.P27385= (on ENST00000591111; = p.P19961= on NM_003319.4) | Silent (SNP) | VAF 33/472 reads (7%) | catalogued as rs772691207; called by muse, mutect2
- USP27X | c.1080C>T p.N360= | Silent (SNP) | VAF 240/508 reads (47%) | catalogued as rs782453783; called by muse, mutect2, varscan2
- WASHC2A | c.1269C>T p.S423= | Silent (SNP) | VAF 25/820 reads (3%) | catalogued as rs539802591, COSV50955131; called by muse, mutect2
- WDR90 | c.1392C>T p.S464= | Silent (SNP) | VAF 129/299 reads (43%) | catalogued as rs368146656; called by muse, mutect2, varscan2
- XKR5 | c.1887G>A p.P629= | Silent (SNP) | VAF 30/369 reads (8%) | catalogued as rs552537442; called by muse, mutect2
- XPO6 | c.1882C>T p.L628= | Silent (SNP) | VAF 11/266 reads (4%) | catalogued as rs1453826157; called by muse, mutect2
- ZNF236 | c.2667G>A p.T889= | Silent (SNP) | VAF 139/315 reads (44%) | catalogued as rs751901638, COSV53492608; called by muse, mutect2, varscan2
- ZNF592 | c.1086G>A p.P362= | Silent (SNP) | VAF 387/813 reads (48%) | catalogued as rs759430463, COSV55434991; called by muse, mutect2, varscan2
- ZNF75A | c.738A>G p.T246= | Silent (SNP) | VAF 21/311 reads (7%) | catalogued as rs1405676211; called by muse, mutect2
- ZSWIM4 | c.816C>T p.G272= | Silent (SNP) | VAF 190/444 reads (43%) | catalogued as rs963305187; called by muse, mutect2, varscan2
- AC134312.1 | n.1028dup | RNA (INS) | VAF 84/232 reads (36%) | called by mutect2, pindel, varscan2
- ACP2 | c.639+66C>T | Intron (SNP) | VAF 263/585 reads (45%) | catalogued as rs1189501638; called by muse, mutect2, varscan2
- ADGRL2 | c.3625+815del | Intron (DEL) | VAF 16/36 reads (44%) | catalogued as rs540574861; called by mutect2, varscan2
- AL109984.1 | n.186+5072G>T | Intron (SNP) | VAF 243/570 reads (43%) | catalogued as COSV63751961; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500581 C>T | 5'Flank (SNP) | VAF 168/349 reads (48%) | catalogued as rs755618497; called by muse, mutect2, varscan2
- AP1B1 | c.2766+101C>T | Intron (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2
- ATAD3A | chr1:1509262 G>A | 5'Flank (SNP) | VAF 218/528 reads (41%) | catalogued as rs753025056; called by muse, mutect2, varscan2
- BCHE | c.1685-4272G>T | Intron (SNP) | VAF 87/245 reads (36%) | called by muse, mutect2, varscan2
- BEST1 | c.1739+128C>T | Intron (SNP) | VAF 58/118 reads (49%) | catalogued as rs571740954, COSV99861321; called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38989dup | Intron (INS) | VAF 83/494 reads (17%) | catalogued as rs1428737276; called by mutect2, varscan2
- BTF3 | c.575-30dup | Intron (INS) | VAF 72/181 reads (40%) | called by mutect2, pindel, varscan2
- C3orf18 | c.*707del | 3'UTR (DEL) | VAF 72/188 reads (38%) | catalogued as rs1275428648; called by mutect2, pindel, varscan2
- C8orf82 | c.157-334del | Intron (DEL) | VAF 59/158 reads (37%) | catalogued as rs1172643553; called by mutect2, pindel, varscan2
- C9orf116 | c.143+224dup | Intron (INS) | VAF 65/197 reads (33%) | catalogued as rs1170595299; called by mutect2, pindel, varscan2
- CACNB4 | c.148-88135G>A | Intron (SNP) | VAF 176/356 reads (49%) | catalogued as rs1009244112; called by muse, mutect2, varscan2
- CAPN1 | chr11:65181670 del C | 5'Flank (DEL) | VAF 42/108 reads (39%) | called by mutect2, pindel, varscan2
- CARD9 | c.1269+78G>A | Intron (SNP) | VAF 41/83 reads (49%) | catalogued as rs762471346; called by muse, mutect2, varscan2
- CARS1 | c.26-5668C>T | Intron (SNP) | VAF 16/272 reads (6%) | catalogued as rs749663366, COSV53452281; called by muse, mutect2
- CD55 | c.1081+1135dup | Intron (INS) | VAF 120/345 reads (35%) | called by mutect2, pindel, varscan2
- CELF2 | c.1076-2187C>T | Intron (SNP) | VAF 132/258 reads (51%) | catalogued as rs761736942; called by muse, mutect2, varscan2
- CEP104 | c.566+1596C>T | Intron (SNP) | VAF 76/154 reads (49%) | catalogued as rs1239972500; called by muse, mutect2, varscan2
- CLK2P1 | n.1291G>A | RNA (SNP) | VAF 112/219 reads (51%) | catalogued as rs754640471; called by muse, mutect2, varscan2
- CPLANE1 | c.*2645del | 3'UTR (DEL) | VAF 108/292 reads (37%) | catalogued as rs769153428, CD150481; called by mutect2, pindel, varscan2
- CTAG2 | c.-56C>T | 5'UTR (SNP) | VAF 74/253 reads (29%) | catalogued as rs782375900; called by muse, mutect2, varscan2
- DENND4B | c.-3del | 5'UTR (DEL) | VAF 34/80 reads (43%) | catalogued as rs770832731; called by mutect2, varscan2
- DIP2A | c.1922-82G>A | Intron (SNP) | VAF 137/153 reads (90%) | catalogued as rs768096198; called by muse, mutect2, varscan2
- DKC1 | c.-15G>A | 5'UTR (SNP) | VAF 40/767 reads (5%) | catalogued as rs373433875; called by muse, mutect2
- DNM1P47 | n.2700C>T | RNA (SNP) | VAF 178/2044 reads (9%) | catalogued as rs752064701; called by muse, varscan2
- DYNLT1 | c.272-10C>T | Intron (SNP) | VAF 10/270 reads (4%) | catalogued as rs1199286137; called by muse, mutect2
- EBAG9 | c.522-1031A>G | Intron (SNP) | VAF 56/126 reads (44%) | catalogued as rs1363384008; called by muse, mutect2, varscan2
- EDA | c.396+4212G>T | Intron (SNP) | VAF 77/196 reads (39%) | called by muse, mutect2, varscan2
- ENAH | c.803-142C>T | Intron (SNP) | VAF 17/584 reads (3%) | called by muse, mutect2
- ERBB4 | c.2487+37del | Intron (DEL) | VAF 137/354 reads (39%) | called by mutect2, pindel, varscan2
- ERGIC3 | chr20:35560147 G>A | 3'Flank (SNP) | VAF 145/295 reads (49%) | catalogued as rs1335918330; called by muse, mutect2, varscan2
- FAM20A | c.*742del | 3'UTR (DEL) | VAF 132/296 reads (45%) | catalogued as rs772873230; called by mutect2, varscan2
- FBLN2 | c.*227C>T | 3'UTR (SNP) | VAF 83/165 reads (50%) | called by muse, mutect2, varscan2
- FBXO30 | chr6:145791681 C>A | 3'Flank (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- FN3K | c.591+51C>T | Intron (SNP) | VAF 281/595 reads (47%) | catalogued as rs772197390, COSV56182459; called by muse, mutect2, varscan2
- GAK | c.3283+160A>G | Intron (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- GATM | c.288+33C>T | Intron (SNP) | VAF 180/395 reads (46%) | catalogued as rs768844434; called by muse, mutect2, varscan2
- GCH1 | c.*17-63del | Intron (DEL) | VAF 54/66 reads (82%) | catalogued as rs918838734; called by mutect2, varscan2
- GDF6 | c.*2G>A | 3'UTR (SNP) | VAF 191/508 reads (38%) | catalogued as rs200117791; called by muse, mutect2, varscan2
- GGTLC2 | chr22:22643879 C>T | 5'Flank (SNP) | VAF 431/1067 reads (40%) | catalogued as rs879541593; called by muse, mutect2, varscan2
- GPS1 | c.*288G>A | 3'UTR (SNP) | VAF 21/137 reads (15%) | catalogued as rs755133243, COSV100152472; called by muse, mutect2, varscan2
- GRIK4 | c.907-2464C>T | Intron (SNP) | VAF 33/214 reads (15%) | called by muse, mutect2, varscan2
- IL1RAP | chr3:190656219 G>A | 3'Flank (SNP) | VAF 19/360 reads (5%) | called by muse, mutect2
- INSL3 | chr19:17821522 C>T | 5'Flank (SNP) | VAF 34/67 reads (51%) | catalogued as rs369090214; called by muse, mutect2, varscan2
- ITGB1BP2 | c.-7C>T | 5'UTR (SNP) | VAF 119/233 reads (51%) | catalogued as rs749756910; called by muse, mutect2, varscan2
- KCND3 | c.-29C>T | 5'UTR (SNP) | VAF 256/570 reads (45%) | catalogued as rs1261568072, COSV56178598; called by muse, mutect2, varscan2
- KNG1 | c.306+23G>T | Intron (SNP) | VAF 20/485 reads (4%) | called by muse, mutect2
- LARGE1 | c.615+26C>T | Intron (SNP) | VAF 237/499 reads (47%) | catalogued as rs774775433; called by muse, mutect2, varscan2
- LINC01100 | n.167del | RNA (DEL) | VAF 116/339 reads (34%) | called by mutect2, pindel, varscan2
- LSM14B | c.427+1315G>A | Intron (SNP) | VAF 265/529 reads (50%) | catalogued as rs1228884300; called by muse, mutect2, varscan2
- MED25 | c.2146+13G>A | Intron (SNP) | VAF 30/545 reads (6%) | catalogued as rs1465846829; called by muse, mutect2
- MIB2 | c.1318-28dup | Intron (INS) | VAF 18/35 reads (51%) | called by mutect2, varscan2
- MKRN9P | n.55del | RNA (DEL) | VAF 36/98 reads (37%) | called by mutect2, varscan2
- MTCL1 | c.2968-3220del | Intron (DEL) | VAF 78/206 reads (38%) | called by mutect2, varscan2
- NEU4 | c.457+373del | Intron (DEL) | VAF 85/186 reads (46%) | catalogued as rs1018792174; called by mutect2, pindel, varscan2
- NHP2 | c.336+11C>T | Intron (SNP) | VAF 268/583 reads (46%) | catalogued as rs369560609; called by muse, mutect2, varscan2
- NPEPL1 | chr20:58691432 del A | 5'Flank (DEL) | VAF 46/166 reads (28%) | catalogued as rs538087084; called by mutect2, varscan2
- NPIPB1P | n.1079G>A | RNA (SNP) | VAF 271/631 reads (43%) | catalogued as rs759101230; called by muse, varscan2
- NRXN1 | c.3365-109829del | Intron (DEL) | VAF 74/644 reads (11%) | catalogued as rs775682152; called by mutect2, varscan2
- NUTM2F | c.*5C>T | 3'UTR (SNP) | VAF 32/64 reads (50%) | catalogued as rs1325259098, COSV99479831; called by mutect2, varscan2
- PLEKHA6 | c.1525-960G>A | Intron (SNP) | VAF 73/176 reads (41%) | catalogued as rs779093314, COSV99692982; called by muse, mutect2, varscan2
- PLEKHM1P1 | n.660C>T | RNA (SNP) | VAF 287/649 reads (44%) | catalogued as rs766393483; called by muse, mutect2, varscan2
- POLG | c.2734+13C>T | Intron (SNP) | VAF 359/751 reads (48%) | catalogued as rs756271228; called by muse, mutect2, varscan2
- PPP4R1L | n.1720A>G | RNA (SNP) | VAF 119/259 reads (46%) | called by muse, mutect2, varscan2
- PRDX4 | c.476+35del | Intron (DEL) | VAF 106/270 reads (39%) | called by mutect2, varscan2
- PRPF31 | c.-8-19C>T | Intron (SNP) | VAF 242/276 reads (88%) | catalogued as rs373990452; called by muse, mutect2, varscan2
- PUSL1 | c.700-89C>T | Intron (SNP) | VAF 223/498 reads (45%) | catalogued as rs548777597; called by muse, mutect2, varscan2
- PXN | c.14-313G>A | Intron (SNP) | VAF 213/502 reads (42%) | catalogued as rs898020143; called by muse, mutect2, varscan2
- RANBP1 | c.310+246C>T | Intron (SNP) | VAF 146/294 reads (50%) | catalogued as rs755478450; called by muse, mutect2, varscan2
- RELL1 | c.*3+8511C>T | Intron (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- RNF149 | c.*39C>T | 3'UTR (SNP) | VAF 32/193 reads (17%) | called by muse, mutect2, varscan2
- RPAIN | c.314-511C>T | Intron (SNP) | VAF 34/76 reads (45%) | catalogued as rs1330664977; called by muse, mutect2, varscan2
- RPL36A | chrX:101390943 C>T | 5'Flank (SNP) | VAF 35/201 reads (17%) | called by muse, mutect2, varscan2
- SCN4B | c.*2330T>A | 3'UTR (SNP) | VAF 278/589 reads (47%) | catalogued as rs1445145488, COSV100228811; called by muse, mutect2, varscan2
- SGSM3 | c.2172+51G>A | Intron (SNP) | VAF 95/219 reads (43%) | catalogued as rs377041526; called by muse, mutect2, varscan2
- SLC29A3 | c.*385G>A | 3'UTR (SNP) | VAF 138/344 reads (40%) | catalogued as rs748101019; called by muse, mutect2, varscan2
- TCEAL4 | c.-3A>G | 5'UTR (SNP) | VAF 12/394 reads (3%) | catalogued as rs1291397967; called by muse, mutect2
- TPSD1 | chr16:1262931 del G | 3'Flank (DEL) | VAF 136/353 reads (39%) | catalogued as rs1276808820; called by mutect2, varscan2
- UFSP2 | c.1122-47C>T | Intron (SNP) | VAF 17/204 reads (8%) | catalogued as rs764503305; called by muse, mutect2
- URM1 | c.238-11_238-10del | Intron (DEL) | VAF 42/308 reads (14%) | called by pindel, varscan2
- Unknown | chr2:217713090 ins C | IGR (INS) | VAF 116/307 reads (38%) | catalogued as rs148961389; called by mutect2, varscan2
- WLS | c.379+10364G>A | Intron (SNP) | VAF 65/131 reads (50%) | catalogued as rs758437066; called by muse, mutect2, varscan2
- ZFC3H1 | c.1015+317del | Intron (DEL) | VAF 11/80 reads (14%) | called by mutect2, varscan2
- ZNF169 | c.256+378C>T | Intron (SNP) | VAF 9/31 reads (29%) | catalogued as rs1298887380; called by muse, mutect2, varscan2
